Somatic mutation profile of tumor specimen 0DSR51 from CCDI case PBCIRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 5.0 years (1,842 days).
Specimen 0DSR51: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c289d8ad-27dc-4751-a859-b5ffe3ed52f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSR5D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba90ccd3-6a45-4171-83d4-1a5aa77e454c

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Intron 2, Nonsense Mutation 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 178/662 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 307/861 reads (36%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 113/228 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by muse, mutect2, varscan2
- CCDC168 | c.19036G>A p.A6346T | Missense Mutation (SNP) | VAF 265/621 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.282); catalogued as rs1484145583; called by muse, mutect2, varscan2
- NLRP11 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 151/347 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.049); catalogued as rs142033132; called by muse, mutect2, varscan2
- RIMKLB | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 48/627 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV55236342; called by muse, mutect2
- SMARCA5 | c.1756G>C p.D586H | Missense Mutation (SNP) | VAF 24/733 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51647220; called by muse, mutect2
- ZBED9 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101509341; called by muse, mutect2
- AIFM1 | c.1604A>C p.E535A | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 44/1111 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- NAP1L3 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 109/776 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NCKAP5 | c.4437C>G p.C1479W | Missense Mutation (SNP) | VAF 292/956 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NF1 | c.4466_4476del p.S1489Kfs*3 (on ENST00000358273 / NM_001042492.3; = p.S1468Kfs*3 on NM_000267.3) | Frame Shift Del (DEL) | VAF 202/756 reads (27%) | called by mutect2, varscan2
- PPP1R3A | c.1957A>T p.K653* | Nonsense Mutation (SNP) | VAF 63/1171 reads (5%) | called by muse, mutect2
- SF3B2 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 21/608 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- VHLL | c.291C>G p.H97Q | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ZNF239 | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 199/746 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- ADCY5 | c.2158C>T p.L720= | Silent (SNP) | VAF 108/549 reads (20%) | called by muse, mutect2, varscan2
- ADGRB3 | c.1047G>A p.E349= | Silent (SNP) | VAF 32/650 reads (5%) | called by muse, mutect2
- BFSP1 | c.888G>A p.A296= | Silent (SNP) | VAF 89/570 reads (16%) | catalogued as rs749513994, COSV100925375; called by muse, mutect2, varscan2
- NUP98 | c.2745T>C p.T915= | Silent (SNP) | VAF 161/948 reads (17%) | called by muse, mutect2, varscan2
- OPN1SW | c.603G>A p.T201= | Silent (SNP) | VAF 255/671 reads (38%) | catalogued as rs748309609; called by muse, mutect2, varscan2
- ZNF316 | c.435C>T p.D145= | Silent (SNP) | VAF 15/369 reads (4%) | catalogued as rs949825000, COSV66385291; called by muse, mutect2
- ANKRD28 | c.2784-37G>A | Intron (SNP) | VAF 9/215 reads (4%) | called by muse, mutect2
- C5orf60 | n.2467C>T | RNA (SNP) | VAF 22/315 reads (7%) | catalogued as rs1351780408; called by muse, mutect2
- NCAPH2 | c.861+113C>G | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs998143555; called by mutect2, varscan2
